MMRF case MMRF_1244 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a6533b38-fe7d-4c1c-951c-c868e9377af6

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.2 years (25,642 days); ISS stage: II; Days to last known disease status: 172 days; Days to last follow up: 172 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 158 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 1): M Protein 4.78 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 104 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.624 mg/dL; Immunoglobulin G 66 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 5.33 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.08 mmol/L; Albumin 30 g/L; Glucose 5.34 mmol/L; C-Reactive Protein 3.35 mg/dL.
- Day 81 (ECOG 1): M Protein 3.49 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 87.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.488 mg/dL; Immunoglobulin G 39.3 g/L; Immunoglobulin A 0.04 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 3.82 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 9.2 g/dL; Glucose 3.91 mmol/L.
- Day 172 (ECOG 1): M Protein 2.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.185 mg/dL; Immunoglobulin G 24.3 g/L; Immunoglobulin A 0.03 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 12.5 ×10⁹/L; Absolute Neutrophil 11.6 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 1.93 mmol/L; Albumin 37 g/L; Total Protein 7.8 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day -10: Weight: 58 kg; Height: 156 cm.

Biospecimens (1 sample)
- Sample MMRF_1244_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
